Somatic mutation profile of tumor specimen 0DRZIZ from CCDI case PBCHJK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 11.1 years (4,069 days).
Specimen 0DRZIZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4ecb562-30a9-41e0-a124-ca9c72c2e7fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRZJJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/973c8158-f3fb-4bfa-bbd0-33603a802d00

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR2K2 | c.968A>G p.K323R (on ENST00000374428; = p.K294R on NM_205859.2) | Missense Mutation (SNP) | VAF 33/796 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as rs1040102335; called by muse, mutect2
- PRKCG | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 33/378 reads (9%) | catalogued as rs1246087299; called by muse, mutect2
- PARP14 | c.1844A>G p.K615R | Missense Mutation (SNP) | VAF 169/563 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- RAB3C | c.155A>T p.D52V | Missense Mutation (SNP) | VAF 57/683 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ADHFE1 | c.822C>A p.G274= | Silent (SNP) | VAF 235/801 reads (29%) | called by muse, mutect2, varscan2
- SHROOM2 | c.4410C>T p.A1470= | Silent (SNP) | VAF 120/314 reads (38%) | catalogued as rs756879119; called by muse, mutect2, varscan2
- NADSYN1 | c.798+77C>T | Intron (SNP) | VAF 11/48 reads (23%) | catalogued as rs566768885; called by muse, mutect2, varscan2
